CCDI case PBBIEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dde4d814-20b2-439b-bd41-f27d7f852ba2

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,053 days).

Biospecimens (4 samples)
- Sample 0D920O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D92H5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D9OOA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9OOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
